Somatic mutation profile of tumor specimen TCGA-VD-AA8R-01A (aliquot TCGA-VD-AA8R-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8R, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.0 years (28,841 days).
Specimen TCGA-VD-AA8R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3acd7e4f-1e8a-4148-a808-e09598949ba9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8R-10A (Blood Derived Normal), aliquot TCGA-VD-AA8R-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fba42d6-650f-4267-96c4-4cc9b2d90398

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 37/41 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63309376; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BICC1 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs755739904; called by muse, mutect2, varscan2
- GLI2 | c.4591C>T p.R1531* (on ENST00000361492 / NM_001374353.1; = p.R1548* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | catalogued as COSV58046108; called by muse, mutect2, varscan2
- GNB3 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1041974039; called by muse, mutect2, varscan2
- MUC5AC | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); catalogued as rs1357774544, COSV100650586; called by muse, mutect2, varscan2
- MYH2 | c.5405G>A p.R1802H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs777282924, COSV55447559, COSV55449799; called by muse, mutect2, varscan2
- RYR1 | c.6212G>A p.R2071Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.27); catalogued as rs139775280, COSV62099638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTSE1 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAI14 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- SZT2 | c.9240C>T p.A3080= (on ENST00000634258 / NM_001365999.1; = p.A3023= on NM_015284.4) | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
